Gene-level copy-number profile of tumor specimen CDDP-ABK0-TTP1-A from CDDP_EAGLE case CDDP-ABK0, project CDDP_EAGLE-1: CDDP Integrative Analysis of Lung Adenocarcinoma (Phase 2). Sex at birth: male; Vital status: Dead; Primary diagnosis: Acinar cell carcinoma; Tissue or organ of origin: Upper lobe, lung; AJCC pathologic stage: Stage IIA; Age at diagnosis: 62 years.
Specimen CDDP-ABK0-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file bde0130c-a46f-4098-a300-9b66830d2de7.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator CDDP-ABK0-NB1-A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,716 have no estimate.
https://portal.gdc.cancer.gov/files/5f18f53e-d0ed-4ad8-bd3b-f8018d1f2ebd

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 429; copy number 1: 10,355; copy number 2: 40,826; copy number 3: 4,707; copy number 4: 1,612; copy number 5: 540; copy number 6: 205; copy number 7: 91; copy number 8: 52; copy number 9: 44; copy number 10: 25; copy number 11: 18; copy number 12: 3.

Homozygous deletions (total copy number 0; autosomes only): 68 genes in 6 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:167,916,675–167,937,072, 1 gene (within-gene range 0–3): MPC2.
- chr1:167,998,660–167,998,726, 1 gene (within-gene range 0–3): MIR1255B2.
- chr8:12,362,019–12,388,296, 3 genes: FAM66A, AC087203.1, AC087203.2.
- chr9:21,329,665–26,118,408, 55 genes: KLHL9, IFNA6, IFNA13, IFNA2, AL353732.1, IFNA11P, IFNA12P, IFNA8, AL353732.2, IFNWP2, IFNA1, MIR31HG, IFNWP19, IFNE, MIR31, SNORD39, H3P30, KHSRPP1, RN7SL151P, MTAP, AL359922.1, TUBB8P1, AL359922.2, AL359922.3, ERVFRD-3, CDKN2A-DT, CDKN2A, CDKN2B-AS1, AL449423.1, CDKN2B, UBA52P6, AL354709.1, AL354709.2, AL157937.1, DMRTA1, LINC01239, AL391117.1, CLIC4P1, AC017067.1, AL445623.2, SUMO2P2, AL445623.1, NOP56P2, ELAVL2, AL365204.1, AL365204.2, AL365204.3, IZUMO3, AL353811.1, RMRPP5, RN7SKP120, TUSC1, LINC01241, FAM71BP1, AL353753.1.
- chr17:18,450,244–18,475,920, 4 genes (within-gene range 0–1): KRT16P4, AL353997.1, AL353997.4, TNPO1P2.
- chr17:18,497,095–18,551,705, 4 genes (within-gene range 0–1): NOS2P2, FAM106A, USP32P2, SRP68P2.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 978 genes in 26 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:146,472,566–147,295,765, 19 genes, copy number 6 (within-gene range 3–6): HYDIN2, RNA5SP536, AC241929.1, NBPF12, PFN1P8, AC244394.3, AC244394.2, AC244394.1, RNU1-151P, SSBL4P, RNVU1-8, NBPF13P, PRKAB2, PDIA3P1, AC242426.2, FMO5, CCT8P1, RPL7AP15, CHD1L.
- chr1:149,197,992–155,278,491, 339 genes, copy number 5 (within-gene range 3–5) (broad region; genes not listed).
- chr1:156,668,763–157,138,474, 24 genes, copy number 6–7: NES, AL590666.3, AL590666.4, CRABP2, AL590666.1, ISG20L2, RRNAD1, MRPL24, HDGF, PRCC, AL590666.5, SH2D2A, NTRK1, INSRR, PEAR1, LRRC71, ARHGEF11, MIR765, RN7SL612P, SMU1P1, KRT8P45, ETV3L, ETV3, CYCSP52.
- chr1:160,876,540–161,766,227, 62 genes, copy number 6 (broad region; genes not listed).
- chr1:196,774,813–196,795,407, 1 gene, copy number 7: CFHR3.
- chr2:173,871,653–174,502,312, 20 genes, copy number 5: RPL5P7, SP3, AC016737.1, AC016737.2, LINC01960, RPSAP24, OLA1, AC013467.1, RN7SL65P, Y_RNA, LRRC2P1, HNRNPA1P39, LINC01305, AC018470.1, SP9, CIR1, SCRN3, GPR155, AC010894.1, RPA3P1.
- chr2:175,842,887–176,095,944, 6 genes, copy number 5: EXTL2P1, AC016751.2, AC016751.1, LNPK, EVX2, HOXD13.
- chr2:190,607,660–192,776,899, 29 genes, copy number 5: AC006460.2, NAB1, AC006460.1, AC005540.1, GLS, STAT1, RAB1AP1, AC067945.1, AC067945.2, STAT4, AC067945.3, RNU6-959P, AC079777.1, HMGB1P27, AC092614.1, MYO1B, RNU6-1045P, NABP1, AC114778.1, AC098872.1, CAVIN2, CAVIN2-AS1, DNAJB1P1, TMEFF2, AC062039.1, AC013401.1, PCGEM1, RPS17P8, AC013401.2.
- chr8:78,148,101–78,153,913, 1 gene, copy number 11: AC084706.1.
- chr8:81,791,823–81,842,866, 3 genes, copy number 10: AC132219.1, SNX16, HNRNPA1P36.
- chr8:88,032,011–88,328,025, 1 gene, copy number 5 (within-gene range 4–5): MMP16.
- chr8:89,900,721–90,053,633, 4 genes, copy number 7: RNU6-925P, OSGIN2, NBN, DECR1.
- chr8:90,621,995–95,811,254, 99 genes, copy number 5–10 (broad region; genes not listed).
- chr8:99,013,266–99,877,580, 1 gene, copy number 6 (within-gene range 4–6): VPS13B.
- chr8:99,527,826–100,776,865, 35 genes, copy number 5–6: Y_RNA, MIR599, MIR875, RN7SL350P, AC018442.1, AC018442.2, AC018442.3, COX6C, AC105328.1, RGS22, SNORD77B, AC021590.1, FBXO43, POLR2K, SPAG1, Y_RNA, AC025647.1, Y_RNA, RNF19A, AP001574.1, AP003472.1, MIR4471, AP003472.2, AP000424.1, AP000424.2, ANKRD46, GAPDHP62, SNX31, AP001205.1, RNU6-1092P, PABPC1, MIR7705, RNU6ATAC41P, Y_RNA, RPS20P23.
- chr8:102,826,308–103,002,424, 6 genes, copy number 6 (within-gene range 4–6): AZIN1, AP003696.1, MAILR, AP003354.1, RPL5P24, Y_RNA.
- chr8:123,768,439–132,481,095, 116 genes, copy number 6–12 (broad region; genes not listed).
- chr8:133,191,039–134,390,487, 21 genes, copy number 9: CCN4, NDRG1, KC877373.1, AF186190.1, ST13P6, ST3GAL1, AC103706.2, AC103706.3, AC103706.1, AC090821.1, Metazoa_SRP, MTND2P7, MTCO1P49, AC133634.1, AC090821.2, AC090821.3, AC110741.1, AC110741.3, AC110741.2, AC105180.2, AC105180.1.
- chr8:137,105,352–137,105,458, 1 gene, copy number 5: RNU6-144P.
- chr8:141,207,166–142,705,127, 32 genes, copy number 8–11 (within-gene range 2–11): SLC45A4, AC011676.5, AC011676.1, AC011676.2, AC011676.3, AC011676.4, LINC01300, AC100803.3, GPR20, AC100803.2, PTP4A3, MROH5, AC100803.4, AC100803.1, HNRNPA1P38, AC138647.1, AC104417.1, AC104417.2, AC103758.1, MIR4472-1, LINC00051, TSNARE1, RN7SL260P, AC134682.1, ADGRB1, MROH4P, ARC, AP006547.1, AC108002.2, JRK, PSCA, LY6K.
- chr10:17,315,421–21,526,368, 59 genes, copy number 6: ST8SIA6, ST8SIA6-AS1, Y_RNA, PRPF38AP2, HACD1, AC069542.2, STAM-AS1, STAM, AC069542.1, TMEM236, MRC1, MIR511, AC069023.1, SLC39A12, SLC39A12-AS1, CACNB2, AL390783.1, AL450384.2, AL450384.1, NSUN6, ARL5B, AL512641.1, AIFM1P1, AL357520.1, MALRD1, UBE2V2P1, AL590378.1, HMGN1P20, AL354695.1, U3, RNA5SP303, AL157895.1, MTND1P37, MTND2P16, RNU6-1212P, AL353147.1, PLXDC2, AC069549.1, AC069549.2, AMD1P1, AL590032.1, MIR4675, NEBL, MTND1P21, AL157398.1, EIF4BP2, NPM1P30, NEBL-AS1, AL731547.1, LUZP4P1, RNU6-15P, LINC02643, RNMTL1P1, AL158209.1, Metazoa_SRP, Y_RNA, MIR1915HG, MIR1915, SKIDA1.
- chr10:27,110,111–28,941,910, 46 genes, copy number 5: YME1L1, MASTL, ACBD5, RNU2-24P, RNU7-12P, AL160291.1, LRRC37A6P, ARMC4P1, AL355493.6, RNU6-666P, AL355493.1, RNU6-452P, LINC02673, FAM210CP, TRIAP1P1, PTCHD3, RAB18, MKX, MKX-AS1, ARMC4, RN7SKP132, RPL36AP55, AL390866.1, MRPS21P5, MPP7, AL355501.1, MIR8086, MPP7-DT, ZNF101P1, U3, LINC02652, RPSAP10, RN7SKP39, WAC-AS1, WAC, RNU4ATAC6P, TPRKBP1, RNU6-1067P, BAMBI, LINC01517, AL355376.1, RNU6-270P, LINC00837, AL355376.2, RNA5SP308, RPL21P93.
- chr10:47,300,197–49,151,547, 50 genes, copy number 5–8: GDF10, GDF2, RBP3, ZNF488, ANXA8, AL591684.3, FAM25G, AL591684.1, AGAP9, AL591684.2, RNA5SP312, BMS1P2, BX547991.1, DUSP8P1, CTSLP2, LINC02675, SHLD2P3, RN7SL453P, RHEBP2, FO681492.1, AC245041.2, NPY4R2, AC245041.1, FAM25C, AGAP12P, RNA5SP315, BMS1P7, PTPN20CP, FRMPD2, AC074325.1, RPS6P14, MAPK8, AC016397.2, ARHGAP22, ARHGAP22-IT1, AC016397.1, AC068898.2, AC068898.1, WDFY4, RPL13AP19, AC035139.2, AC035139.1, AC060234.3, LRRC18, AC060234.2, AC060234.1, MIR4294, VSTM4, FAM170B-AS1, FAM170B.
- chr11:3,854,318–3,855,509, 1 gene, copy number 5 (within-gene range 2–5): STIM1-AS1.
- chr11:3,854,612–3,855,399, 1 gene, copy number 5 (within-gene range 2–5): AC090587.1.
- chr17:18,476,737–18,494,945, 1 gene, copy number 6: LGALS9C.

Autosomal genes at a single copy (total copy number 1): 7,862. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
